Surgical pathology report (de-identified scan), TCGA case TCGA-A6-2681, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-2681-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Right colon

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cancerous cecum.

GROSS DESCRIPTION

Received fresh labeled "right colon" is a previously unopened 31 cm. segment of proximal right colon with attached 28 cm. of distal ileum surfaced by smooth tan-pink serosa with a copious amount of attached mesentery, mesocolon, and unremarkable omentum. An unremarkable, 3.2 cm. appendix averaging 0.6 cm. in diameter is present. The proximal and distal margins measure 4.2 and 7.0 cm. in circumference respectively. On opening there is a well-circumscribed, 2.8 x 2.5 cm. rubbery tan pink-red tumor mass within the cecal pouch, 2 cm. distal to the ileocecal valve. A portion of tumor and a portion of normal mucosa are submitted for tissue procurement as requested. On sectioning, the tumor has a maximal thickness of 0.6 cm., approaching the muscularis and extending to within 0.5 cm. of the inked free radial serosal surface. The ileal mucosa and uninvolved colonic mucosa is otherwise unremarkable glistening tan-pink with regular folds and the walls average 0.5 cm. in thickness. A few uncomplicated diverticula are evident throughout the colonic segment. Several soft tan pink tissues in keeping with lymph nodes measuring up to 1 cm. in greatest dimension are recovered from the attached mesentery and mesocolon. Representative sections are submitted in fifteen blocks as labeled. RS-15.

BLOCK SUMMARY: 1 - Proximal and distal margins; [**11-01**] - entire lesion;
6 - ileum; 7 - ICV; 8 - random colon; 9 - appendix; 10,11 - eight whole lymph nodes per cassette; 12 - seven whole lymph nodes; 13-15 - one bisected lymph node per cassette. [REDACTED]

GROSS DESCRIPTION

[REDACTED]

[page 2 of 2]
MICROSCOPIC DESCRIPTION

Histologic type: Adenocarcinoma
Histologic grade: Moderately-differentiated
Primary tumor (pT3): Carcinoma extends through the muscularis propria into the subserosal fat.
Proximal/distal/radial margins: Negative
Vascular invasion: Not identified
Regional lymph nodes (pN): twenty-three negative lymph nodes (0/23)
Non-lymph node pericolic tumor: Not identified
Other findings: unremarkable appendix, ileum. Diverticulosis.

5

DIAGNOSIS

Colon, terminal ileum, appendix, right hemicolectomy:
Adenocarcinoma, moderately-differentiated, with invasion through the muscularis propria into the subserosal fat (pT3).
Margins of excision: Negative.
Vascular invasion: Not identified.
Twenty-three negative lymph nodes (0/23)

Source: NCI Genomic Data Commons file 60fc810b-1655-483b-8094-26a447938f04 (TCGA-A6-2681.EC4BB62B-EDF5-4051-8240-4E9D89FD928F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).